Somatic mutation profile of tumor specimen 0D9JPM from CCDI case PBBIVU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.6 years (3,492 days).
Specimen 0D9JPM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b5599dd-6e23-45a4-857f-d92629e8a345.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9JPN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e7b21ac-a9f4-4509-be6c-44d159c8aaa6

The open-access MAF lists 25 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Intron 2, 3'UTR 2, Nonsense Mutation 1, 5'Flank 1, Translation Start Site 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOL5 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 224/539 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.034); catalogued as rs369534518, COSV50766354; called by muse, mutect2, varscan2
- BCL2L14 | c.832G>A p.V278I | Missense Mutation (SNP) | VAF 35/344 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.364); catalogued as rs147550863; called by muse, mutect2
- CTSH | c.73C>A p.L25M | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs541062615; called by mutect2, varscan2
- FLT4 | c.1931C>T p.A644V | Missense Mutation (SNP) | VAF 125/247 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as rs1391338478, COSV56101655; called by muse, mutect2, varscan2
- GCG | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 158/385 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1279952120; called by muse, mutect2, varscan2
- GSE1 | c.1112_1147del p.Q371_E382del | In Frame Del (DEL) | VAF 102/346 reads (29%) | catalogued as rs747022201; called by mutect2, varscan2
- PLXNB2 | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 88/752 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1159157606; called by muse, mutect2, varscan2
- SNX17 | c.962G>A p.W321* | Nonsense Mutation (SNP) | VAF 65/503 reads (13%) | catalogued as COSV52007081; called by muse, mutect2, varscan2
- ARL1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 67/394 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BMPR2 | c.1873G>A p.G625S | Missense Mutation (SNP) | VAF 83/468 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CBFA2T2 | c.1515+1G>T p.X505_splice | Splice Site (SNP) | VAF 161/358 reads (45%) | called by muse, mutect2, varscan2
- CES4A | c.1528G>T p.D510Y (on ENST00000648724 / NM_001364782.1; = p.M442I on NM_173815.7) | Missense Mutation (SNP) | VAF 37/292 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.435); called by mutect2, varscan2
- KCNH3 | c.232C>T p.L78F | Missense Mutation (SNP) | VAF 166/366 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- MON2 | c.3598G>C p.G1200R | Missense Mutation (SNP) | VAF 89/432 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPEN | c.2143A>G p.R715G | Missense Mutation (SNP) | VAF 147/293 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF235 | c.257A>T p.E86V | Missense Mutation (SNP) | VAF 49/384 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF625 | c.77A>G p.K26R | Missense Mutation (SNP) | VAF 32/588 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2
- EPHA10 | c.954C>T p.C318= | Silent (SNP) | VAF 298/680 reads (44%) | catalogued as COSV57626627, COSV57627767; called by muse, mutect2, varscan2
- SEMA3C | c.2190C>T p.G730= | Silent (SNP) | VAF 32/508 reads (6%) | called by muse, mutect2
- UTS2R | c.465G>A p.P155= | Silent (SNP) | VAF 224/652 reads (34%) | catalogued as rs765022861, COSV57453219; called by muse, mutect2, varscan2
- ARHGDIA | c.*491C>T | 3'UTR (SNP) | VAF 308/986 reads (31%) | catalogued as rs143149806, COSV53906307; called by muse, mutect2, varscan2
- AZU1 | c.594+100C>G | Intron (SNP) | VAF 21/41 reads (51%) | catalogued as rs1026075091; called by muse, mutect2, varscan2
- FAM53C | chr5:138338007 G>A | 5'Flank (SNP) | VAF 21/425 reads (5%) | called by muse, mutect2
- GRK2 | c.1052+12C>T | Intron (SNP) | VAF 33/253 reads (13%) | catalogued as rs773098927; called by muse, varscan2
- ZSWIM4 | c.*36C>A | 3'UTR (SNP) | VAF 5/71 reads (7%) | catalogued as rs1362514454; called by muse, mutect2
